Somatic mutation profile of cancer-model specimen HCM-BROD-0125-C25-85B (3D Organoid, passage 6; aliquot HCM-BROD-0125-C25-85B-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0125-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 72.9 years (26,629 days).
Specimen HCM-BROD-0125-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82f1c647-c194-4b42-84d0-20e5d92f63f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0125-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0125-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06251adc-15a0-464f-8966-d6de35224a52

The open-access MAF lists 63 somatic variants for this specimen: 45 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 17, Nonsense Mutation 4, In Frame Del 2, Intron 1, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 161/166 reads (97%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.3046C>T p.R1016* | Nonsense Mutation (SNP) | VAF 383/616 reads (62%) | catalogued as rs759085500, COSV100617298; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.431A>C p.Q144P | Missense Mutation (SNP) | VAF 324/324 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs786203071, CM023462, COSV52661000, COSV52675618, COSV52761562, COSV53080684; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- APBA2 | c.2122G>A p.V708M | Missense Mutation (SNP) | VAF 381/384 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538291011, COSV68790237; called by muse, mutect2, varscan2
- C3 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 206/338 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs780884558, COSV55568795; called by muse, mutect2, varscan2
- CAD | c.6086G>A p.G2029E | Missense Mutation (SNP) | VAF 179/368 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1020986533; called by muse, mutect2, varscan2
- COLEC10 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100250981; called by muse, mutect2, varscan2
- FAM24A | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 42/505 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs138688045; called by muse, mutect2
- GRIA4 | c.286G>C p.G96R | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56905172; called by muse, mutect2, varscan2
- L3MBTL1 | c.414del p.S139Afs*9 (on ENST00000418998 / NM_001377303.1; = p.S49Afs*9 on NM_015478.7) | Frame Shift Del (DEL) | VAF 335/812 reads (41%) | catalogued as COSV100917301; called by mutect2, pindel, varscan2
- MAGEB6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.64); catalogued as rs775370255, COSV66872399; called by muse, mutect2
- MAP7D2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 212/218 reads (97%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as rs771369178, COSV65527357; called by muse, mutect2, varscan2
- NRXN3 | c.2420G>C p.R807P (on ENST00000335750 / NM_001330195.2; = p.R434P on NM_004796.6) | Missense Mutation (SNP) | VAF 223/428 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59758617; called by muse, mutect2, varscan2
- PCDHGA3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 401/652 reads (62%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV53923997; called by muse, mutect2, varscan2
- PPM1F | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1474170519; called by muse, mutect2, varscan2
- PSD2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 217/658 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs764425844, COSV51197172; called by muse, mutect2, varscan2
- SCN2A | c.4990G>A p.G1664S | Missense Mutation (SNP) | VAF 54/551 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99332149; called by muse, mutect2, varscan2
- WRNIP1 | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV66356388; called by muse, mutect2
- ZNF440 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs530490353, COSV58371088; called by muse, mutect2, varscan2
- ACRBP | c.944+6G>C | Splice Region (SNP) | VAF 332/337 reads (99%) | called by muse, mutect2, varscan2
- ADGRL1 | c.1472C>T p.P491L (on ENST00000340736 / NM_001008701.3; = p.P486L on NM_014921.5) | Missense Mutation (SNP) | VAF 117/520 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ARHGAP32 | c.1603A>T p.I535L (on ENST00000310343 / NM_001378025.1; = p.I186L on NM_014715.4) | Missense Mutation (SNP) | VAF 105/161 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- AUH | c.212T>G p.M71R | Missense Mutation (SNP) | VAF 21/884 reads (2%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- B3GALT5 | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 202/202 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- CRACDL | c.942C>G p.H314Q | Missense Mutation (SNP) | VAF 94/970 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.084); called by muse, mutect2
- CROT | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 36/328 reads (11%) | called by muse, mutect2, varscan2
- DSG3 | c.2968T>A p.C990S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.093); called by muse, mutect2
- EXOC5 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRMD8 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HELZ2 | c.1939A>G p.T647A (on ENST00000467148 / NM_001037335.2; = p.T78A on NM_033405.3) | Missense Mutation (SNP) | VAF 66/891 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ILDR2 | c.97A>G p.M33V | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- IRX2 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 614/974 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRGUK | c.671-1G>C p.X224_splice | Splice Site (SNP) | VAF 9/190 reads (5%) | called by muse, mutect2
- LRRC2 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 208/344 reads (60%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- MYH13 | c.4921G>A p.A1641T | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- NCAN | c.2643G>C p.K881N | Missense Mutation (SNP) | VAF 16/503 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.348); called by muse, mutect2
- NCR3LG1 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 279/279 reads (100%) | called by muse, mutect2, varscan2
- OR52E6 | c.282A>G p.I94M | Missense Mutation (SNP) | VAF 157/159 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- PLEKHH2 | c.2632C>G p.R878G | Missense Mutation (SNP) | VAF 23/454 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2
- SATB1 | c.88A>T p.I30F | Missense Mutation (SNP) | VAF 129/404 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TAF4 | c.2510_2512del p.V837del | In Frame Del (DEL) | VAF 192/426 reads (45%) | called by mutect2, pindel, varscan2
- TMEM38A | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 145/392 reads (37%) | called by muse, mutect2, varscan2
- ZC3H6 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 217/451 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF746 | c.701A>T p.D234V | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2
- ZNF865 | c.1417_1431del p.P473_A477del | In Frame Del (DEL) | VAF 124/300 reads (41%) | called by mutect2, pindel, varscan2
- AKAP9 | c.10524G>A p.Q3508= (on ENST00000359028; = p.Q3484= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/271 reads (11%) | called by muse, mutect2, varscan2
- BLVRA | c.787T>C p.L263= | Silent (SNP) | VAF 20/558 reads (4%) | called by muse, mutect2
- CLDN8 | c.264C>T p.S88= | Silent (SNP) | VAF 225/225 reads (100%) | catalogued as rs372970119, COSV99729682; called by muse, mutect2, varscan2
- CSMD2 | c.3972C>T p.D1324= | Silent (SNP) | VAF 115/367 reads (31%) | catalogued as rs769259843; called by muse, mutect2, varscan2
- DHX38 | c.3270C>T p.Y1090= | Silent (SNP) | VAF 126/209 reads (60%) | catalogued as rs111685951; called by muse, mutect2, varscan2
- DIP2C | c.900C>T p.A300= | Silent (SNP) | VAF 212/477 reads (44%) | catalogued as rs1459415150; called by muse, mutect2, varscan2
- DNMT1 | c.3108C>T p.H1036= | Silent (SNP) | VAF 263/413 reads (64%) | catalogued as rs141856197; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- EHBP1 | c.1428A>G p.L476= | Silent (SNP) | VAF 142/328 reads (43%) | called by muse, mutect2, varscan2
- ELFN2 | c.2103G>A p.P701= | Silent (SNP) | VAF 80/513 reads (16%) | catalogued as COSV68745626; called by muse, mutect2, varscan2
- FBN3 | c.6234G>A p.P2078= | Silent (SNP) | VAF 212/349 reads (61%) | catalogued as rs772743589; called by muse, mutect2, varscan2
- HYDIN | c.6486C>T p.S2162= | Silent (SNP) | VAF 50/214 reads (23%) | catalogued as rs201229423; called by muse, mutect2, varscan2
- IZUMO4 | c.33G>A p.T11= | Silent (SNP) | VAF 162/451 reads (36%) | catalogued as COSV100642754, COSV100643115, COSV61433378; called by muse, mutect2, varscan2
- LDB2 | c.990G>T p.A330= | Silent (SNP) | VAF 22/472 reads (5%) | catalogued as COSV58769101; called by muse, mutect2
- LOXHD1 | c.1950C>T p.N650= | Silent (SNP) | VAF 76/76 reads (100%) | catalogued as rs371762941; ClinVar: likely benign; called by muse, mutect2, varscan2
- MNDA | c.336G>A p.A112= | Silent (SNP) | VAF 232/531 reads (44%) | catalogued as rs780583002, COSV63740866; called by muse, mutect2, varscan2
- OR9H1P | c.486C>T p.F162= | Silent (SNP) | VAF 42/546 reads (8%) | catalogued as rs1261110835; called by muse, mutect2
- ZDHHC11B | c.153C>T p.G51= | Silent (SNP) | VAF 421/893 reads (47%) | catalogued as rs762369299, COSV66978013; called by muse, mutect2, varscan2
- TNRC18 | c.487+119_487+126del | Intron (DEL) | VAF 58/292 reads (20%) | catalogued as rs11295332; called by mutect2, pindel*
